Somatic mutation profile of tumor specimen MP2PRT-PATCEA-TMP1-A (aliquot MP2PRT-PATCEA-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATCEA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (836 days).
Specimen MP2PRT-PATCEA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1c19413-48dc-40e5-b5db-4772c623bb3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATCEA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATCEA-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e44e7f24-d0af-456d-b55f-eadb46913b34

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 68/264 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.1229C>T p.T410M | Missense Mutation (SNP) | VAF 83/345 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs780030998, COSV52302342; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 68/272 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB6 | c.2061C>A p.Y687* | Nonsense Mutation (SNP) | VAF 135/593 reads (23%) | catalogued as rs372749168; called by muse, mutect2, varscan2
- POU2F2 | c.883G>A p.G295S (on ENST00000526816 / NM_001207025.3; = p.G279S on NM_002698.5) | Missense Mutation (SNP) | VAF 133/468 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.923); catalogued as COSV100657582; called by muse, mutect2, varscan2
- CCSER2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 90/322 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- RETNLB | c.179G>C p.S60T | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TBC1D26 | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 13/416 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2
- DACT2 | c.2025G>A p.P675= | Silent (SNP) | VAF 155/675 reads (23%) | catalogued as rs1471495887; called by muse, mutect2, varscan2
- MYO1F | c.1308C>A p.I436= | Silent (SNP) | VAF 91/315 reads (29%) | called by muse, mutect2, varscan2
